Somatic mutation profile of tumor specimen TCGA-49-6744-01A (aliquot TCGA-49-6744-01A-11D-1855-08) from TCGA case TCGA-49-6744, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 64.3 years (23,484 days).
Specimen TCGA-49-6744-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6680da97-11ec-49b1-8ebf-698f5e20b6a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-6744-11A (Solid Tissue Normal), aliquot TCGA-49-6744-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/047c7c3b-0baa-41fe-91c7-e3c59a55bdc3

The open-access MAF lists 219 somatic variants for this specimen: 168 protein-altering or splice-affecting, 49 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 139, Silent 49, Nonsense Mutation 19, Splice Site 4, Frame Shift Del 3, Splice Region 2, 5'Flank 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.364A>G p.N122D | Missense Mutation (SNP) | VAF 95/398 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV55598968; called by muse, mutect2, varscan2
- ACTG2 | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 5/70 reads (7%) | catalogued as COSV100609503; called by muse, mutect2
- ADAD1 | c.1219C>A p.Q407K | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); catalogued as COSV56646836; called by muse, mutect2
- ADAMTS14 | c.2548G>T p.E850* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as COSV64599775, COSV64605755; called by muse, mutect2, varscan2
- ADCY4 | c.2834C>A p.A945E | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60257154; called by muse, mutect2, varscan2
- ADCY4 | c.1837G>T p.A613S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV60257163; called by muse, mutect2, varscan2
- ADGRB3 | c.525G>T p.L175F | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.979); catalogued as COSV65415661, COSV65427482; called by muse, mutect2, varscan2
- ADGRG4 | c.4447G>T p.D1483Y | Missense Mutation (SNP) | VAF 19/285 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV54953975, COSV54964949; called by muse, mutect2
- AGGF1 | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs1369844215, COSV57231012; called by muse, mutect2, varscan2
- AKR1D1 | c.486G>C p.L162F | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54340357; called by muse, mutect2, varscan2
- ANK1 | c.3544C>A p.Q1182K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.179); catalogued as COSV55893199; called by muse, mutect2, varscan2
- ANK2 | c.4171C>A p.P1391T | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52183913; called by muse, mutect2
- ARAP2 | c.2443G>T p.A815S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1316640251, COSV58291281; called by muse, mutect2
- ARPP21 | c.2109C>A p.N703K | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs369106158; called by muse, mutect2, varscan2
- ASTN1 | c.3395G>T p.R1132L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100705342, COSV62504579; called by muse, mutect2, varscan2
- ATP1B4 | c.498C>G p.N166K (on ENST00000218008 / NM_001142447.3; = p.N162K on NM_012069.5) | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.815); catalogued as COSV54314649; called by muse, mutect2
- CASP5 | c.543G>T p.E181D | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV52831246; called by muse, mutect2
- CBLL1 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.402); catalogued as COSV56028177; called by muse, mutect2
- CCDC88B | c.1724C>G p.S575C | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.204); catalogued as COSV57267833; called by muse, mutect2
- CCDC96 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 29/199 reads (15%) | catalogued as COSV100028109; called by muse, mutect2, varscan2
- CCT6B | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58491489; called by muse, mutect2, varscan2
- CDH7 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59893067; called by muse, mutect2, varscan2
- CEP250 | c.5429G>C p.R1810T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.496); catalogued as COSV61170348; called by muse, mutect2, varscan2
- CLDN11 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV50356020; called by muse, mutect2
- CMKLR1 | c.650A>T p.H217L (on ENST00000312143 / NM_001142344.2; = p.H215L on NM_004072.3) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as rs1342225025, COSV56441465; called by muse, mutect2
- CNTNAP2 | c.1174C>A p.Q392K | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV62243961; called by muse, mutect2, varscan2
- CNTNAP2 | c.1804T>A p.Y602N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62243964; called by muse, mutect2, varscan2
- COL16A1 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs758332125, COSV99595478; called by mutect2, varscan2
- COL3A1 | c.58A>G p.I20V | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1342128671, COSV58595362; called by muse, mutect2
- COL7A1 | c.5135G>T p.G1712V | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.978); catalogued as COSV60401989, COSV60404152; called by muse, mutect2
- CPQ | c.745G>T p.G249W | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55158077; called by mutect2, varscan2
- CSAG3 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 50/512 reads (10%) | catalogued as rs1196731548; called by muse, mutect2
- CSMD3 | c.105G>T p.M35I | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV52103977, COSV52294512; called by muse, varscan2
- CUL2 | c.283A>T p.S95C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66080666; called by muse, mutect2, varscan2
- CYLC1 | c.943A>G p.K315E | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.501); catalogued as COSV61415293; called by muse, mutect2, varscan2
- DCHS1 | c.5159C>T p.T1720I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55041585; called by muse, mutect2
- DDB1 | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57105251; called by muse, mutect2, varscan2
- DDX59 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV58753768; called by muse, mutect2
- DISP3 | c.248G>T p.S83I | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.026); catalogued as COSV53835929; called by muse, mutect2, varscan2
- DNAH7 | c.8737G>T p.G2913* | Nonsense Mutation (SNP) | VAF 23/100 reads (23%) | catalogued as COSV56781668; called by muse, mutect2, varscan2
- EFCAB7 | c.465T>A p.D155E | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV64315254; called by muse, mutect2, varscan2
- EGFLAM | c.1754C>A p.A585D | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59314789; called by muse, mutect2, varscan2
- EPHB6 | c.1685G>T p.R562L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63893304; called by muse, mutect2, varscan2
- EPYC | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as COSV99664913; called by muse, mutect2, varscan2
- F5 | c.2945G>A p.W982* | Nonsense Mutation (SNP) | VAF 12/241 reads (5%) | catalogued as COSV63127552; called by muse, mutect2
- FAAP100 | c.923A>G p.H308R | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.206); catalogued as COSV59887282; called by muse, mutect2, varscan2
- FAM135B | c.3899C>G p.T1300R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV52749047; called by mutect2, varscan2
- FCAR | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as rs535382825, COSV62028980, COSV62031573; called by muse, mutect2, varscan2
- FHOD1 | c.2615C>G p.P872R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50767615; called by muse, mutect2, varscan2
- FLG2 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 39/393 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.938); catalogued as COSV66166710; called by muse, mutect2, varscan2
- GABRA3 | c.1379G>T p.R460L | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64796181, COSV64805725; called by muse, mutect2, varscan2
- GALNT8 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.281); catalogued as COSV52901088; called by muse, mutect2, varscan2
- GALNTL6 | c.83G>A p.W28* | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | catalogued as COSV72553121; called by muse, mutect2
- GREB1 | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV52194904; called by muse, mutect2, varscan2
- GREB1 | c.3163T>A p.C1055S | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV52194928; called by muse, mutect2
- HLA-DQA2 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as COSV66566521; called by muse, mutect2, varscan2
- HMCN1 | c.15053G>A p.G5018E | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54934271; called by muse, mutect2, varscan2
- HMGCR | c.2546G>T p.G849V | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99843487; called by muse, mutect2
- HOXA9 | c.569C>G p.P190R | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.102); catalogued as rs771349569, COSV100604505; called by muse, mutect2, varscan2
- IGHMBP2 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54825805; called by muse, mutect2
- IL1RAPL1 | c.311G>T p.W104L | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56254266; called by muse, mutect2
- ITGA10 | c.2212C>T p.Q738* | Nonsense Mutation (SNP) | VAF 25/99 reads (25%) | catalogued as COSV65198889; called by muse, mutect2, varscan2
- ITGAM | c.667G>T p.G223W | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54941649; called by muse, mutect2
- JAK3 | c.2906G>T p.G969V | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71687365; called by muse, mutect2, varscan2
- KIF19 | c.138C>A p.D46E | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63430444; called by muse, mutect2, varscan2
- KIF21B | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.996); catalogued as COSV100145145; called by muse, mutect2, varscan2
- KMT2C | c.691G>C p.V231L | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV51491983; called by muse, mutect2, varscan2
- KRBA1 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55443856; called by muse, mutect2
- KRT40 | c.670A>T p.K224* | Nonsense Mutation (SNP) | VAF 12/116 reads (10%) | catalogued as COSV66696856; called by muse, mutect2, varscan2
- L1CAM | c.1024C>A p.H342N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.035); catalogued as COSV100649471; called by muse, mutect2, varscan2
- LOX | c.1003C>A p.H335N | Missense Mutation (SNP) | VAF 27/317 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV99140724; called by muse, mutect2
- LRRN3 | c.701G>C p.G234A | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57823353; called by muse, mutect2, varscan2
- LUZP2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.056); catalogued as COSV61216432; called by muse, mutect2
- LYAR | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 7/112 reads (6%) | catalogued as COSV58643885; called by muse, mutect2
- MAF | c.89T>A p.F30Y | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100391999; called by muse, mutect2
- MAP3K5 | c.974A>T p.Q325L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV62891639; called by muse, mutect2, varscan2
- MARCHF8 | c.799G>T p.G267* | Nonsense Mutation (SNP) | VAF 12/123 reads (10%) | catalogued as COSV60574472; called by muse, mutect2, varscan2
- MEFV | c.1098C>A p.S366R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV54826580; called by muse, mutect2, varscan2
- MROH9 | c.1104G>C p.L368F | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV63012965; called by muse, mutect2
- MYH1 | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV55446932; called by muse, mutect2, varscan2
- MYH9 | c.4867G>T p.E1623* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV53384506; called by muse, varscan2
- MYO1H | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs1224296592, COSV100184014, COSV100184055; called by muse, mutect2, varscan2
- MYO5B | c.2871G>C p.M957I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV53228831, COSV53232096; called by muse, mutect2, varscan2
- NAV3 | c.38C>A p.P13Q | Missense Mutation (SNP) | VAF 53/285 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as rs1366502744, COSV57107513; called by muse, mutect2, varscan2
- NETO1 | c.1448C>A p.S483* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV55013797; called by muse, mutect2, varscan2
- NUP62 | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV61313392, COSV61313860; called by muse, mutect2, varscan2
- OCA2 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); catalogued as COSV62356151; called by muse, mutect2, varscan2
- OR14A16 | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV100713868; called by muse, mutect2
- OR2AE1 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100318403; called by muse, mutect2, varscan2
- OR2AG1 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56627078; called by muse, mutect2, varscan2
- OR2F2 | c.558G>T p.R186S | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101283855; called by muse, mutect2
- OR2F2 | c.865A>C p.I289L | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1376069031, COSV101283856; called by muse, mutect2
- OR2J2 | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 73/451 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV65848341; called by muse, mutect2, varscan2
- OR4P4 | c.572A>C p.H191P | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.433); catalogued as COSV58920790; called by muse, mutect2, varscan2
- OR4P4 | c.573C>A p.H191Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100111867; called by muse, mutect2, varscan2
- OR51B5 | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56177087; called by mutect2, varscan2
- PAK1 | c.1066G>T p.V356L | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV53700646; called by muse, mutect2, varscan2
- PCDH10 | c.718G>C p.V240L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52102381; called by muse, mutect2, varscan2
- PCDHGA1 | c.1748A>T p.E583V | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV65298970; called by muse, mutect2
- PCDHGA8 | c.2300A>C p.H767P | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV54016648; called by muse, mutect2, varscan2
- PDZRN4 | c.2176G>T p.E726* (on ENST00000402685 / NM_001164595.2; = p.E468* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 18/166 reads (11%) | catalogued as COSV54210280, COSV54214691, COSV54217599; called by muse, mutect2
- PEAR1 | c.1293C>G p.G431= | Splice Region (SNP) | VAF 19/83 reads (23%) | catalogued as COSV52775496; called by muse, mutect2, varscan2
- PIWIL1 | c.357C>A p.F119L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV55351074; called by muse, mutect2, varscan2
- PKHD1 | c.1694-2A>G p.X565_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | catalogued as COSV61891688; called by muse, mutect2, varscan2
- PLCB1 | c.2089G>T p.V697L | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV62038471, COSV62065133; called by muse, mutect2, varscan2
- PPP1R15B | c.658T>A p.S220T | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV65816471; called by muse, mutect2
- PRDM9 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 38/289 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs754142725, COSV57009588, COSV57012020; called by muse, mutect2, varscan2
- PTGS2 | c.1119G>C p.W373C | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66571397; called by muse, mutect2
- RABGGTA | c.1504G>T p.D502Y | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV52865104; called by muse, mutect2, varscan2
- RBFOX1 | c.1135C>A p.L379I | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV60954007, COSV60977981; called by muse, mutect2, varscan2
- RBM27 | c.3178A>G p.R1060G | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54593605; called by muse, mutect2
- REG1A | c.322-2A>G p.X108_splice | Splice Site (SNP) | VAF 13/164 reads (8%) | catalogued as COSV52071245; called by muse, mutect2
- RPGRIP1 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.024); catalogued as COSV52856028; called by muse, mutect2, varscan2
- RTL5 | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65454693; called by muse, mutect2, varscan2
- RXFP3 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV57507611; called by muse, mutect2, varscan2
- RYR2 | c.8945T>G p.F2982C | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63688641; called by muse, mutect2
- RYR2 | c.10687C>A p.Q3563K | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV63693429; called by muse, mutect2
- SEMA4D | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs929801490, COSV59396561; called by muse, mutect2
- SEMA5A | c.2515C>A p.P839T | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV66803686; called by muse, mutect2, varscan2
- SETBP1 | c.3517C>G p.L1173V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56334704; called by mutect2, varscan2
- SETD2 | c.4547G>T p.C1516F | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57441296, COSV57443398, COSV57448602; called by muse, mutect2, varscan2
- SHC2 | c.1254G>T p.Q418H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV52748950; called by muse, varscan2
- SI | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 37/650 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.057); catalogued as COSV52297468; called by muse, mutect2
- SIK2 | c.795C>G p.I265M | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59255569; called by muse, mutect2, varscan2
- SLC13A5 | c.1336G>T p.A446S | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV53424808, COSV99546255; called by muse, mutect2
- SLC14A2 | c.2745G>T p.Q915H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.527); catalogued as COSV54913847; called by muse, mutect2
- SLC24A5 | c.155C>A p.S52* | Nonsense Mutation (SNP) | VAF 6/140 reads (4%) | catalogued as COSV58319140; called by muse, mutect2
- SLC25A41 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV58600714; called by muse, mutect2, varscan2
- SLC35F4 | c.827C>A p.T276K (on ENST00000339762 / NM_001352015.2; = p.T240K on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104410243, COSV60266801; called by muse, mutect2, varscan2
- SLC6A16 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs377673703, COSV60029826; called by muse, mutect2, varscan2
- SLC8A1 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60494202, COSV60497847; called by muse, mutect2, varscan2
- SLITRK3 | c.2262del p.I755Sfs*38 | Frame Shift Del (DEL) | VAF 18/133 reads (14%) | catalogued as COSV53849687, COSV99578690; called by mutect2, pindel, varscan2
- SPATA18 | c.1468A>T p.R490* | Nonsense Mutation (SNP) | VAF 10/168 reads (6%) | catalogued as COSV54649308; called by muse, mutect2
- SPEG | c.8843G>C p.S2948T | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV56678255; called by muse, mutect2
- SSX5 | c.232G>T p.D78Y (on ENST00000347757 / NM_175723.1; = p.D119Y on NM_021015.4) | Missense Mutation (SNP) | VAF 16/283 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61256360; called by muse, mutect2
- SYT9 | c.146-1G>C p.X49_splice | Splice Site (SNP) | VAF 22/168 reads (13%) | catalogued as COSV59623999; called by muse, mutect2, varscan2
- SYTL5 | c.1537C>A p.P513T | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.181); catalogued as COSV52904891; called by muse, mutect2
- TAAR8 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 56/304 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV51587093; called by muse, mutect2, varscan2
- TBX1 | c.817G>T p.V273F | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60352564, COSV60355114; called by muse, mutect2
- TEKT4 | c.1171C>A p.R391S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs72817671; called by muse, mutect2
- TENM3 | c.2824C>A p.L942I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV101305468; called by muse, mutect2, varscan2
- TIMMDC1 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV51787866; called by muse, mutect2, varscan2
- TP53BP1 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV55503156; called by muse, mutect2
- TRPM6 | c.3619C>T p.Q1207* | Nonsense Mutation (SNP) | VAF 17/117 reads (15%) | catalogued as COSV62520760; called by muse, mutect2, varscan2
- TTN | c.27040T>G p.S9014A (on ENST00000591111; = p.S8087A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/311 reads (21%) | PolyPhen benign (0.015); catalogued as COSV60293856; called by muse, mutect2, varscan2
- TUBB2B | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99455664; called by mutect2, varscan2
- TULP4 | c.2963G>A p.R988Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.435); catalogued as rs143675661; called by muse, mutect2
- VCX3B | c.77C>A p.P26Q | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.033); catalogued as COSV101123821; called by muse, mutect2, varscan2
- VPS13B | c.4229G>T p.R1410I | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV62154646; called by muse, mutect2
- VWCE | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as rs749427323, COSV57113794; called by muse, mutect2, varscan2
- WDR62 | c.1832A>T p.Q611L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV54338849; called by muse, mutect2, varscan2
- WDR64 | c.1734G>T p.M578I | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63799757; called by muse, mutect2, varscan2
- WNK3 | c.4811C>A p.T1604K | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV63615611; called by muse, mutect2
- WWC3 | c.1798G>C p.G600R | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV66506647, COSV66508449; called by muse, mutect2
- ZAN | c.7405G>T p.G2469* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV61814944; called by muse, mutect2, varscan2
- ZFHX4 | c.6999G>T p.K2333N | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs1288561734, COSV51491233, COSV99070797; called by muse, mutect2, varscan2
- ZNF277 | c.727A>G p.M243V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs777414185, COSV62465960; called by mutect2, varscan2
- ZNF385D | c.46C>A p.L16I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV55771550; called by muse, mutect2, varscan2
- ZNF536 | c.1599G>T p.M533I | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV62819251, COSV62832800; called by muse, mutect2
- ZNF836 | c.2491G>T p.D831Y | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV100441301; called by muse, mutect2, varscan2
- ZWINT | c.799G>T p.G267C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs1389321820, COSV59185310; called by muse, mutect2, varscan2
- GALE | c.988+2dup | Splice Region (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel
- GGNBP2 | c.1021A>T p.M341L | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- IFNAR2 | c.1081del p.D361Tfs*31 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | called by mutect2, pindel, varscan2
- MAX | c.13dup p.D5Gfs*2 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | called by pindel, varscan2
- MED13 | c.1101_1102del p.P368Qfs*10 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | called by mutect2, pindel, varscan2
- MRPL45 | c.362+1G>T p.X121_splice | Splice Site (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2, varscan2
- PCDHB14 | c.1547T>A p.L516H | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ACTG2 | c.138G>T p.V46= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV100609500; called by muse, mutect2
- CHUK | c.894A>T p.P298= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV64918621; called by muse, mutect2, varscan2
- CNTNAP2 | c.3066A>G p.P1022= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as rs1178918214, COSV62243970; called by muse, mutect2, varscan2
- COL5A2 | c.3768G>T p.A1256= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV66407627, COSV66414160; called by muse, mutect2, varscan2
- CUL4B | c.2301C>A p.I767= | Silent (SNP) | VAF 43/331 reads (13%) | catalogued as COSV60690603; called by muse, mutect2, varscan2
- DNAH8 | c.4587A>T p.I1529= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV59475339; called by muse, mutect2, varscan2
- DNPEP | c.1011C>T p.C337= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV56111780; called by muse, mutect2
- EPYC | c.192A>T p.S64= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV99664916; called by muse, mutect2, varscan2
- FLG | c.4335G>A p.V1445= | Silent (SNP) | VAF 12/357 reads (3%) | catalogued as COSV64239829; called by muse, mutect2
- FMO2 | c.102T>G p.T34= | Silent (SNP) | VAF 10/216 reads (5%) | catalogued as COSV52949967; called by muse, mutect2
- FRS3 | c.312G>T p.L104= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as COSV99443147; called by muse, mutect2
- GPRASP1 | c.1263C>A p.A421= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV64356345; called by muse, mutect2, varscan2
- HEATR1 | c.4236C>T p.L1412= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV63982776; called by muse, mutect2
- IL1RAPL2 | c.213G>T p.G71= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as COSV61153546, COSV61177691; called by muse, mutect2, varscan2
- KLF17 | c.66G>T p.A22= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100955019, COSV64856703; called by muse, mutect2, varscan2
- MEDAG | c.831A>T p.S277= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV66850766; called by muse, mutect2, varscan2
- MORC1 | c.267G>T p.R89= | Silent (SNP) | VAF 12/161 reads (7%) | catalogued as rs747172427, COSV51729103; called by muse, mutect2
- MUC16 | c.20868C>G p.T6956= | Silent (SNP) | VAF 22/200 reads (11%) | catalogued as rs1242352800, COSV67474574, COSV67488594; called by muse, mutect2
- MUC17 | c.6051C>T p.T2017= | Silent (SNP) | VAF 49/357 reads (14%) | catalogued as COSV60300796; called by muse, mutect2, varscan2
- MYH9 | c.4866G>T p.L1622= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV99339839; called by muse, mutect2
- MYPN | c.2988A>T p.R996= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV62738165; called by muse, mutect2, varscan2
- NAIF1 | c.150C>T p.G50= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV66092232; called by muse, mutect2, varscan2
- OR2M4 | c.279T>C p.S93= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV60709467; called by muse, mutect2, varscan2
- OR52E6 | c.588C>A p.V196= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV100259556, COSV61432300; called by muse, mutect2
- OR5B17 | c.684A>T p.T228= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV62160319, COSV62160985; called by muse, mutect2, varscan2
- OR5L2 | c.165C>A p.L55= | Silent (SNP) | VAF 22/374 reads (6%) | catalogued as COSV65724978; called by muse, mutect2
- PCBP3 | c.915A>T p.I305= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as COSV68409767; called by muse, mutect2
- PCDHA7 | c.1089C>A p.A363= | Silent (SNP) | VAF 9/201 reads (4%) | catalogued as COSV65346875; called by muse, mutect2
- PCDHB14 | c.1548C>A p.L516= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV99506284; called by muse, mutect2
- PDE6C | c.486C>T p.S162= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV65117392; called by muse, mutect2
- PDZRN3 | c.894G>T p.L298= | Silent (SNP) | VAF 17/301 reads (6%) | catalogued as COSV55213472; called by muse, mutect2
- PEX26 | c.270C>A p.I90= | Silent (SNP) | VAF 24/139 reads (17%) | catalogued as COSV61605187; called by muse, mutect2, varscan2
- PPM1L | c.828C>T p.N276= | Silent (SNP) | VAF 5/89 reads (6%) | catalogued as rs952397683, COSV99862072; called by muse, mutect2
- PRPS2 | c.480C>A p.A160= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as rs1225867738, COSV66126592; called by muse, mutect2
- PSME4 | c.3765T>A p.T1255= | Silent (SNP) | VAF 12/224 reads (5%) | catalogued as COSV66367198; called by muse, mutect2
- RASGRF2 | c.2343T>C p.T781= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV54138061; called by muse, mutect2
- REEP4 | c.370C>A p.R124= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV57942895, COSV57943090; called by muse, mutect2, varscan2
- RELB | c.1716A>G p.L572= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV55509415; called by muse, mutect2, varscan2
- SLC12A9 | c.1212G>A p.L404= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV51936543; called by muse, mutect2, varscan2
- SLF2 | c.1002A>G p.E334= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV53278843; called by muse, mutect2
- SNRPB | c.222G>T p.G74= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV60016407; called by muse, mutect2
- STYXL2 | c.1629C>A p.A543= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV54809280; called by muse, mutect2, varscan2
- TENM3 | c.2823C>A p.T941= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV101305467; called by muse, mutect2, varscan2
- TESK1 | c.369A>T p.G123= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV52412295; called by muse, mutect2, varscan2
- TRAV7 | c.135G>T p.T45= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- TTN | c.100614C>G p.T33538= (on ENST00000591111; = p.T26114= on NM_003319.4) | Silent (SNP) | VAF 19/432 reads (4%) | catalogued as COSV60293793; called by muse, mutect2
- USF3 | c.2280T>A p.P760= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV57076654; called by muse, mutect2
- ZNF260 | c.315C>T p.H105= | Silent (SNP) | VAF 11/160 reads (7%) | catalogued as COSV101591057; called by muse, mutect2
- ZNF772 | c.450C>A p.G150= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV58411614; called by muse, mutect2
- AP000769.3 | chr11:65505171 T>C | 5'Flank (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- CFAP47 | c.5536-492dup | Intron (INS) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
